Somatic mutation profile of tumor specimen TCGA-JW-AAVH-01A (aliquot TCGA-JW-AAVH-01A-11D-A387-09) from TCGA case TCGA-JW-AAVH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 46.3 years (16,894 days).
Specimen TCGA-JW-AAVH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a249095-8155-4a3f-b54f-950af7abea94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-AAVH-10A (Blood Derived Normal), aliquot TCGA-JW-AAVH-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffddf152-aee6-4ffc-8bba-60148b128528

The open-access MAF lists 115 somatic variants for this specimen: 82 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 30, Nonsense Mutation 8, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 76/82 reads (93%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 6/79 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCA2 | c.3662G>A p.R1221H (on ENST00000614293; = p.R1191H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99687162; called by muse, mutect2, varscan2
- ADAM19 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs200776477, COSV99978791; called by muse, mutect2, varscan2
- ADGRV1 | c.6658G>A p.E2220K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.214); catalogued as COSV101316674; called by muse, mutect2, varscan2
- ADRA2C | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342874997, COSV100342709; called by muse, mutect2, varscan2
- ANKFN1 | c.1870C>G p.Q624E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); catalogued as COSV100594349; called by muse, mutect2, varscan2
- ANKRD11 | c.5197G>A p.A1733T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs780508146, COSV99970921; called by muse, mutect2, varscan2
- ASPH | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV101064580; called by muse, mutect2, varscan2
- ATP13A2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs776601823, COSV58698349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL9 | c.4111C>T p.H1371Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs782398061, COSV99325545, COSV99326027; called by muse, mutect2, varscan2
- BCOR | c.1132A>G p.T378A | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as COSV100654356; called by muse, mutect2, varscan2
- BEST2 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | catalogued as rs760251223, COSV99244734; called by muse, mutect2, varscan2
- C6orf62 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016174; called by muse, mutect2, varscan2
- CCDC14 | c.1846G>T p.D616Y (on ENST00000488653; = p.D568Y on NM_022757.5) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100113249, COSV100113449; called by muse, mutect2, varscan2
- CHD4 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100539495; called by muse, mutect2, varscan2
- CPSF6 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as rs995232341, COSV99879754; called by muse, mutect2
- CYB561 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100669217; called by muse, mutect2, varscan2
- DAW1 | c.855C>G p.C285W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100006611, COSV59369290; called by muse, mutect2, varscan2
- DHX16 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as rs765508826, COSV100905277; called by muse, mutect2, varscan2
- DMD | c.7470T>A p.D2490E | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as CX1410244, COSV100629830; called by muse, mutect2, varscan2
- DYNC2I1 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101337750; called by muse, mutect2, varscan2
- ECM1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs587674518, COSV60872074; called by muse, mutect2, varscan2
- FAM47C | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 177/495 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100793017; called by muse, mutect2, varscan2
- FLRT2 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV58141126; called by muse, mutect2, varscan2
- FRZB | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV54555024; called by muse, mutect2, varscan2
- G6PC3 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99291422; called by muse, mutect2, varscan2
- GCOM1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs374890020, COSV99985427; called by muse, mutect2
- GGCX | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52089424; called by muse, mutect2, varscan2
- GPHN | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.063); catalogued as COSV59482353; called by muse, mutect2, varscan2
- GUCY1A2 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.829); catalogued as COSV56494027, COSV99974023; called by muse, mutect2, varscan2
- HORMAD1 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100464547; called by muse, mutect2, varscan2
- HOXB7 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV99494245; called by muse, mutect2, varscan2
- IKZF1 | c.810C>G p.N270K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100498862, COSV58785910; called by muse, mutect2, varscan2
- ITGAL | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.058); catalogued as rs377233189, COSV63321914; called by muse, mutect2, varscan2
- KCNH5 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100528211; called by muse, mutect2, varscan2
- LRP12 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.117); catalogued as COSV99408481; called by muse, mutect2, varscan2
- LSM14B | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99444883; called by muse, mutect2, varscan2
- MAGEB6 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 39/123 reads (32%) | catalogued as COSV100983897; called by muse, mutect2, varscan2
- MANBAL | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV101009507; called by muse, varscan2
- MCF2L2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100194213; called by muse, mutect2, varscan2
- MYH7B | c.1588C>G p.Q530E | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53416695, COSV99483446; called by muse, mutect2, varscan2
- NR3C2 | c.832C>G p.H278D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV100679938; called by mutect2, varscan2
- OR10A4 | c.494del p.F165Sfs*11 | Frame Shift Del (DEL) | VAF 37/81 reads (46%) | catalogued as rs749714974; called by mutect2, pindel, varscan2
- P2RY10 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99409465; called by muse, mutect2, varscan2
- PCNT | c.9420G>C p.L3140F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64024831; called by muse, mutect2
- PIGF | c.460A>G p.S154G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.334); catalogued as COSV99851432; called by muse, mutect2, varscan2
- PIKFYVE | c.4835G>A p.G1612E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.843); catalogued as COSV100011633; called by muse, mutect2, varscan2
- PLEKHG4B | c.2829C>A p.Y943* (on ENST00000283426; = p.Y1299* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV52049945, COSV99361298; called by muse, mutect2, varscan2
- PNPLA7 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV99481697; called by muse, varscan2
- POP4 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV99694659; called by muse, mutect2, varscan2
- PPP2R5E | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100518686, COSV100518853, COSV100518891; called by muse, mutect2, varscan2
- PRIM1 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100590511; called by muse, mutect2, varscan2
- PTGFRN | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs773910797, COSV67800041; called by muse, mutect2, varscan2
- PTPRD | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.758); catalogued as rs758577045, COSV100642816, COSV61995148; called by muse, mutect2, varscan2
- RAD21 | c.426G>C p.E142D | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV99815706; called by muse, mutect2, varscan2
- RDH16 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs931225152, COSV62458021; called by muse, mutect2, varscan2
- RFX3 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100176046; called by muse, mutect2, varscan2
- RGS6 | c.669G>C p.L223F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV100667217; called by muse, mutect2
- RHCE | c.851C>G p.S284W | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53799752, COSV53803958, COSV99604527; called by muse, mutect2
- RIT2 | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 53/116 reads (46%) | catalogued as rs1233900623, COSV99951274; called by muse, mutect2, varscan2
- SIM1 | c.1670G>T p.S557I | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV99492934; called by muse, mutect2, varscan2
- SLC45A4 | c.2146T>C p.Y716H (on ENST00000517878 / NM_001286646.2; = p.Y665H on NM_001080431.2) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99201069; called by muse, mutect2
- SLITRK5 | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.827); catalogued as COSV100281331; called by muse, mutect2, varscan2
- SOX11 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100431543; called by muse, mutect2, varscan2
- SYNPO2 | c.1536C>G p.D512E | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100206563; called by muse, mutect2, varscan2
- TENM1 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100951241; called by muse, mutect2, varscan2
- TRPM6 | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as rs755085866; called by mutect2, varscan2
- TSHZ3 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV99553105; called by muse, mutect2
- TTN | c.30196G>C p.E10066Q (on ENST00000591111; = p.E9139Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | PolyPhen benign (0.093); catalogued as COSV100634870; called by muse, mutect2, varscan2
- TUBA4A | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.074); catalogued as COSV99944774; called by muse, mutect2
- USP20 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201524680, COSV100204898; called by muse, mutect2, varscan2
- USP5 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.635); catalogued as COSV99979146; called by muse, mutect2, varscan2
- UTRN | c.2353C>T p.Q785* | Nonsense Mutation (SNP) | VAF 18/29 reads (62%) | catalogued as COSV100840602, COSV62333656; called by muse, mutect2, varscan2
- WBP1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99270630, COSV99270863; called by muse, mutect2
- ZNF254 | c.577A>G p.M193V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV100741817; called by muse, mutect2, varscan2
- DIXDC1 | c.1678_1689+29del p.X560_splice (on ENST00000440460 / NM_001037954.4; = p.X349_splice on NM_033425.4) | Splice Site (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel
- ORC4 | c.1187dup p.R397Efs*12 | Frame Shift Ins (INS) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- PHKA2 | c.2644G>T p.G882W | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SECISBP2 | c.1619_1633dup p.R540_K544dup | In Frame Ins (INS) | VAF 12/52 reads (23%) | called by mutect2, varscan2
- TRIM44 | c.323_324del p.E108Gfs*10 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by pindel, varscan2
- ABCA3 | c.2130G>A p.Q710= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100069226; called by muse, mutect2, varscan2
- ADGRL1 | c.4053G>A p.S1351= (on ENST00000340736 / NM_001008701.3; = p.S1346= on NM_014921.5) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs771522355, COSV100529889; called by muse, varscan2
- ALOX5 | c.1656C>T p.A552= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs149908407; called by muse, mutect2, varscan2
- ARNT | c.2091C>G p.L697= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs756342019, COSV100591450; called by muse, mutect2, varscan2
- CCDC144A | c.63C>T p.Y21= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV61403024; called by muse, mutect2, varscan2
- CD5 | c.24G>A p.P8= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs759739416, COSV61718165; called by muse, mutect2, varscan2
- CLCN4 | c.504C>T p.V168= | Silent (SNP) | VAF 51/169 reads (30%) | catalogued as rs779568555, COSV101074117; called by muse, mutect2, varscan2
- CYP4F11 | c.1452C>T p.L484= | Silent (SNP) | VAF 63/109 reads (58%) | catalogued as COSV56127377; called by muse, mutect2
- DNAH10 | c.12168C>T p.L4056= (on ENST00000409039; = p.L3995= on NM_207437.3) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1469852575, COSV101292970; called by muse, mutect2, varscan2
- DST | c.21477A>T p.A7159= (on ENST00000361203 / NM_001374722.1; = p.A4856= on NM_015548.5) | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99760926; called by muse, varscan2
- FAM47C | c.774C>A p.L258= | Silent (SNP) | VAF 133/481 reads (28%) | catalogued as COSV63731642; called by muse, mutect2, varscan2
- FGFRL1 | c.324G>C p.L108= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs904529586, COSV99294926; called by muse, mutect2, varscan2
- H1-3 | c.327C>T p.N109= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs549014505, COSV99768924; called by muse, mutect2, varscan2
- IGSF10 | c.6426G>A p.R2142= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV99196489; called by muse, mutect2
- KIAA2026 | c.4524T>C p.F1508= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV101199250; called by muse, mutect2, varscan2
- KRTAP10-5 | c.228G>A p.P76= | Silent (SNP) | VAF 85/178 reads (48%) | catalogued as rs368543649; called by muse, mutect2, varscan2
- LAT | c.282G>A p.T94= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs763554523, COSV57953393; called by muse, mutect2, varscan2
- MFHAS1 | c.1230C>T p.L410= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as COSV99360035; called by muse, mutect2, varscan2
- MPDZ | c.6018C>T p.G2006= (on ENST00000319217 / NM_001330637.2; = p.G1977= on NM_003829.5) | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as COSV100057839; called by muse, mutect2, varscan2
- NIFK | c.303A>C p.I101= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs373704889; called by muse, mutect2, varscan2
- OR1L4 | c.75G>A p.Q25= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs1389387531, COSV52340438, COSV99413989; called by muse, mutect2, varscan2
- SLC44A2 | c.366G>A p.T122= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs762835831, COSV100213523; called by muse, mutect2, varscan2
- SORBS1 | c.90T>C p.P30= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV99529125; called by muse, mutect2, varscan2
- SREBF1 | c.1117C>T p.L373= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as COSV99888932; called by muse, mutect2, varscan2
- SYNPR | c.75G>A p.L25= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99889468; called by muse, mutect2, varscan2
- TDRD6 | c.255C>T p.R85= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV60179466; called by muse, mutect2, varscan2
- TOX2 | c.627C>G p.T209= (on ENST00000358131 / NM_001098798.2; = p.T158= on NM_032883.3) | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV100364868, COSV57894338; called by muse, mutect2, varscan2
- UBA2 | c.255G>A p.P85= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs772167417, COSV55829247; called by muse, mutect2
- USP22 | c.981C>T p.I327= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV99820570; called by muse, mutect2, varscan2
- USP42 | c.2781C>T p.A927= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs759610637, COSV100085018; called by muse, varscan2
- ANKRD13D | c.*519G>A | 3'UTR (SNP) | VAF 19/57 reads (33%) | catalogued as rs140647228; called by muse, mutect2, varscan2
- DPP6 | c.627+20739G>A | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as rs1339156365, COSV100128756; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1842G>C | Intron (SNP) | VAF 8/22 reads (36%) | catalogued as rs1267024205, COSV100315087; called by muse, mutect2, varscan2
